Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3971, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3971-01A (Primary Tumor).

Diagnosis (diagnoses):

Resected colon sample with a centrally ulcerated, moderately differentiated adenocarcinoma of the colorectal type, measuring a max of 4.8 cm in diameter, with broad infiltration of the pericolic fatty tissue and two local lymph node metastases immediately next to the tumor. Tumor-free colon resection margins. Tumor-free mesenteric resection margin. Otherwise, individual tubular adenomas of the colon mucous membrane with predominant moderate dysplasia (synonym: mild intraepithelial neoplasia).

The tumor stage is: pT2, pN0 (0/27) pMX; G2, L0, V0, R0

Source: NCI Genomic Data Commons file 99124dc5-b607-4c8f-acbc-64f7b92e529b (TCGA-AA-3971.C9868EE7-4CC6-4C5D-AA91-ED744A8FEF35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).